Somatic mutation profile of tumor specimen TCGA-ER-A19K-01A (aliquot TCGA-ER-A19K-01A-21D-A197-08) from TCGA case TCGA-ER-A19K, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 79.2 years (28,946 days).
Specimen TCGA-ER-A19K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee1cf887-53f6-4874-bfb8-3b58bf61af97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19K-10A (Blood Derived Normal), aliquot TCGA-ER-A19K-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09524af0-5201-457c-945e-6bcd4bab0be4

The open-access MAF lists 430 somatic variants for this specimen: 289 protein-altering or splice-affecting, 133 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 269, Silent 133, Nonsense Mutation 11, Splice Region 4, Frame Shift Del 3, RNA 3, Splice Site 2, 3'Flank 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2470C>T p.P824S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV51511501; called by muse, mutect2, varscan2
- ABCB1 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201352027, COSV55949474; called by muse, mutect2, varscan2
- ABCG4 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV56643320; called by muse, varscan2
- ACADM | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63720198; called by muse, mutect2, varscan2
- ACSBG2 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 47/146 reads (32%) | catalogued as COSV53124200; called by muse, mutect2, varscan2
- ADAM29 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867583067, COSV63661697; called by muse, mutect2, varscan2
- ADAM30 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 145/503 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1288491901, COSV65560927; called by muse, mutect2, varscan2
- ADAM7 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51538725; called by muse, mutect2, varscan2
- ADAMTS16 | c.2277C>T p.N759= | Splice Region (SNP) | VAF 32/91 reads (35%) | catalogued as COSV56986199; called by muse, mutect2, varscan2
- ADAMTS20 | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs150670741; called by muse, mutect2, varscan2
- ADCY10 | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as rs754283899, COSV63240130; called by muse, mutect2, varscan2
- ADGRB3 | c.3056G>A p.G1019E | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53242869; called by muse, mutect2, varscan2
- ADRA1A | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1481575037, COSV52362308, COSV52370832; called by muse, mutect2, varscan2
- AFAP1L2 | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV58414056; called by muse, mutect2, varscan2
- AGBL1 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs766419259, COSV69797628; called by muse, mutect2, varscan2
- AGO2 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55046782; called by muse, mutect2, varscan2
- AKAP9 | c.9815C>T p.S3272L (on ENST00000359028; = p.S3248L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); catalogued as COSV62344044; called by muse, mutect2, varscan2
- AL136295.1 | c.2381G>A p.G794D | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV55779191; called by muse, mutect2, varscan2
- ALG13 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV52638013, COSV52645488; called by muse, mutect2, varscan2
- ALKBH1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1165768460, COSV53174049; called by muse, mutect2, varscan2
- ALPL | c.474G>A p.G158= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as rs868361054, COSV66379762; called by muse, mutect2, varscan2
- ANK1 | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV55879579; called by muse, mutect2, varscan2
- ANK3 | c.10325A>G p.K3442R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as COSV55054263; called by muse, mutect2, varscan2
- APOB | c.12706C>T p.H4236Y | Missense Mutation (SNP) | VAF 120/445 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as COSV51932580; called by muse, mutect2, varscan2
- ARFGEF3 | c.2756G>A p.R919Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as rs200406717, COSV52455631; called by muse, mutect2, varscan2
- ARHGEF11 | c.3484G>A p.G1162S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.033); catalogued as COSV59353883; called by muse, mutect2, varscan2
- ASPM | c.4418C>T p.S1473L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV54128567; called by muse, mutect2, varscan2
- ASTN1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.215); catalogued as COSV56066871; called by muse, mutect2, varscan2
- ASTN2 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1309185750, COSV57771760; called by muse, mutect2, varscan2
- ATM | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs1555070869, COSV53739471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRN | c.2214+2T>G p.X738_splice | Splice Site (SNP) | VAF 7/12 reads (58%) | catalogued as COSV53526848; called by muse, mutect2, varscan2
- B3GNT4 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1457634538, COSV57336154; called by muse, mutect2
- BAAT | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV52288529; called by muse, mutect2, varscan2
- BBS12 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV58561890; called by muse, mutect2, varscan2
- BEND4 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.395); catalogued as COSV72469050; called by muse, varscan2
- BSN | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.718); catalogued as COSV56516496; called by muse, mutect2, varscan2
- BTBD11 | c.1990C>T p.P664S (on ENST00000280758 / NM_001018072.2; = p.P201S on NM_001017523.2) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.11); catalogued as COSV55022917, COSV55026670; called by muse, mutect2, varscan2
- C6 | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs533503397, COSV54709066; called by muse, mutect2, varscan2
- C8B | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557740342, COSV64777353; called by muse, mutect2, varscan2
- CAPN10 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371403663, COSV54377797, COSV54378652; called by mutect2, varscan2
- CC2D2B | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs746891421, COSV60357766; called by muse, mutect2, varscan2
- CCDC6 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as COSV54056111; called by muse, mutect2, varscan2
- CCL13 | c.148A>C p.S50R | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56774600; called by muse, mutect2, varscan2
- CD180 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV56517670; called by muse, mutect2, varscan2
- CDR2 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV51676005; called by muse, mutect2, varscan2
- CERKL | c.1235C>T p.S412F (on ENST00000339098 / NM_001030311.2; = p.S386F on NM_201548.5) | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV59206725; called by muse, mutect2, varscan2
- CGNL1 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55563304; called by muse, mutect2, varscan2
- CHRNB3 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV51494590; called by muse, mutect2, varscan2
- CKAP5 | c.5547A>G p.G1849= (on ENST00000529230 / NM_001008938.4; = p.G1789= on NM_014756.3) | Splice Region (SNP) | VAF 5/31 reads (16%) | catalogued as COSV56366988; called by muse, mutect2, varscan2
- CNTN4 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV61871648; called by muse, mutect2, varscan2
- CNTNAP2 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs772138449, COSV62170132; called by muse, mutect2, varscan2
- COL11A2 | c.3907G>A p.G1303R (on ENST00000341947 / NM_080680.3; = p.G1196R on NM_080679.2) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868193306, COSV59496026; called by muse, mutect2, varscan2
- COL8A1 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53730770; called by muse, mutect2, varscan2
- CPLANE2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs141168630; called by muse, mutect2, varscan2
- CRACR2A | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV52912040, COSV99365567; called by muse, mutect2, varscan2
- CRB1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as rs145525029, COSV100959057; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- CRP | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs34340208; called by muse, mutect2, varscan2
- CSMD1 | c.7313C>T p.P2438L (on ENST00000520002; = p.P2437L on NM_033225.6) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs368661303, COSV59312609; called by muse, mutect2, varscan2
- CSMD1 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV68195418; called by muse, mutect2, varscan2
- CTTN | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57231816; called by muse, mutect2, varscan2
- CTTNBP2 | c.3206C>T p.A1069V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs376066347; called by muse, mutect2, varscan2
- CUX2 | c.3517G>A p.V1173M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757404371, COSV55640224, COSV99919668; called by muse, mutect2, varscan2
- CYP2C19 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64907531; called by muse, mutect2, varscan2
- CYP4F2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55622840; called by muse, mutect2, varscan2
- CYP4X1 | c.1074G>A p.W358* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV64150483, COSV64152154; called by muse, mutect2, varscan2
- CYSLTR1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV64819947; called by muse, mutect2, varscan2
- DCDC1 | c.2552G>A p.R851K | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV60840418; called by muse, mutect2, varscan2
- DDI1 | c.955T>C p.S319P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56375461; called by muse, varscan2
- DDI1 | c.983T>G p.M328R | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV56375476; called by muse, varscan2
- DDX43 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV64836782; called by muse, mutect2, varscan2
- DEFB118 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV53620130; called by muse, mutect2, varscan2
- DIP2C | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV55145590, COSV55154790; called by muse, mutect2, varscan2
- DISC1 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs773758385, COSV54405167; called by muse, mutect2, varscan2
- DLL4 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV51061932; called by muse, mutect2
- DNAH10 | c.1367C>T p.A456V (on ENST00000409039; = p.A395V on NM_207437.3) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV101292250; called by muse, mutect2, varscan2
- DNAH5 | c.10024G>A p.E3342K | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV54219398; called by muse, mutect2, varscan2
- DNAH8 | c.9406G>A p.E3136K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.491); catalogued as COSV59434212; called by muse, mutect2, varscan2
- DPYD | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.109); catalogued as rs867226255, COSV64595487; called by muse, mutect2, varscan2
- ELOA2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV55293823, COSV55302873; called by muse, mutect2, varscan2
- EPHA4 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV56028143, COSV56031163; called by muse, mutect2, varscan2
- EWSR1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.737); catalogued as COSV58423109; called by muse, mutect2, varscan2
- EXPH5 | c.3332G>A p.R1111K | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56201263, COSV56208796; called by muse, mutect2, varscan2
- FAM135B | c.2359G>C p.D787H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV52731787, COSV52738227, COSV99426198; called by muse, mutect2, varscan2
- FAM189B | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.981); catalogued as COSV63219100, COSV63219734; called by muse, mutect2, varscan2
- FAT4 | c.4516G>A p.E1506K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV67884615, COSV67898915; called by muse, mutect2, varscan2
- FBXL12 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as rs539610508, COSV56113974; called by mutect2, varscan2
- FCRL5 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs890785912, COSV62510933; called by muse, mutect2, varscan2
- FGA | c.2534C>T p.S845F | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV57393202; called by muse, mutect2, varscan2
- FGFR2 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.496); catalogued as COSV60645360; called by muse, mutect2, varscan2
- FLCN | c.1139A>T p.D380V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.06); catalogued as COSV53258946; called by muse, mutect2, varscan2
- FLG2 | c.4261G>A p.G1421R | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs771730879, COSV101166326, COSV66168512, COSV66168911; called by muse, mutect2, varscan2
- FLG2 | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.92); catalogued as COSV66168109; called by muse, mutect2, varscan2
- FOSB | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.304); catalogued as rs770893486, COSV62278500; called by mutect2, varscan2
- FRAS1 | c.8986G>A p.D2996N | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53587134; called by muse, mutect2, varscan2
- FSTL4 | c.1819C>T p.H607Y | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54768540; called by muse, mutect2, varscan2
- GAL3ST1 | c.743T>A p.L248Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100143077; called by muse, mutect2, varscan2
- GALNT6 | c.1558A>G p.K520E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.944); catalogued as COSV62542019; called by muse, mutect2, varscan2
- GBE1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763302311, COSV70098605; called by muse, mutect2, varscan2
- GEN1 | c.2303T>C p.V768A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV58056307; called by muse, mutect2, varscan2
- GIMAP8 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480798484, COSV56230984; called by muse, mutect2, varscan2
- GNA14 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs773830556, COSV100502962; called by muse, mutect2, varscan2
- GNAI3 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV63983636; called by muse, mutect2, varscan2
- GPR39 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.462); catalogued as COSV61416298; called by muse, mutect2, varscan2
- GPR87 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs866935447, COSV53462862; called by muse, mutect2, varscan2
- GPRIN1 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as rs1317750954, COSV56137748, COSV56146961; called by muse, mutect2, varscan2
- GRIK4 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV70801796; called by muse, mutect2, varscan2
- GRIN3A | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV62452460; called by muse, mutect2, varscan2
- GUCY1A2 | c.1403G>A p.R468K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56484523, COSV99976611; called by muse, mutect2, varscan2
- HBG2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs544071388, COSV57963468; called by muse, mutect2, varscan2
- HIPK1 | c.2522T>C p.L841P | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.136); catalogued as COSV61247382; called by muse, mutect2, varscan2
- HLA-G | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV64405507; called by muse, mutect2, varscan2
- HOXA3 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289116241, COSV57824854, COSV57826051; called by muse, varscan2
- IFT122 | c.2302G>A p.V768M (on ENST00000348417 / NM_052989.3; = p.V709M on NM_018262.4) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs561825107, COSV56202308, COSV56205725, COSV56208976; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFT74 | c.1008T>A p.F336L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV66286623; called by muse, varscan2
- IGSF21 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs149943630; called by muse, mutect2, varscan2
- IL10RA | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV57140307; called by muse, mutect2, varscan2
- IL20RA | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs1216635522, COSV57357814; called by muse, mutect2, varscan2
- ILDR1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0.339); catalogued as COSV56549679; called by muse, mutect2, varscan2
- INPP4A | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV50789630; called by muse, mutect2, varscan2
- INTS2 | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV52152787; called by muse, mutect2, varscan2
- ITPR1 | c.7810G>A p.E2604K (on ENST00000354582; = p.E2549K on NM_002222.7) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56967438; called by muse, mutect2, varscan2
- KAT6A | c.1411T>C p.F471L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0.444); catalogued as rs1357592774, COSV55905314; called by muse, mutect2, varscan2
- KAT6B | c.4232A>G p.E1411G | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV54745684; called by muse, mutect2, varscan2
- KCNC2 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as rs200951837, COSV54367018; called by muse, mutect2, varscan2
- KIAA1549L | c.2587C>G p.H863D (on ENST00000321505; = p.H1160D on NM_012194.3) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV55781589, COSV99683495; called by muse, mutect2
- KLB | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as rs1192494235, COSV57301291; called by muse, mutect2, varscan2
- KNG1 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs201787282, COSV53977320; called by muse, mutect2, varscan2
- KRT222 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67498171, COSV67498509; called by muse, mutect2, varscan2
- LCE3B | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100167542, COSV59500621; called by muse, mutect2, varscan2
- LHCGR | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54296054; called by muse, mutect2, varscan2
- LHCGR | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.197); catalogued as rs200707752, COSV99683716; called by muse, mutect2, varscan2
- LIMCH1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58281378; called by muse, mutect2, varscan2
- LRP1 | c.11663C>T p.S3888L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.06); catalogued as rs745620359, COSV54507955; called by muse, mutect2, varscan2
- LRRC66 | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV58633242; called by muse, mutect2, varscan2
- LRTM1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55531926, COSV55545165; called by muse, mutect2, varscan2
- LSM1 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV60948923; called by muse, mutect2, varscan2
- LTBP2 | c.5461G>A p.E1821K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV56207209; called by muse, mutect2, varscan2
- LYVE1 | c.282C>G p.F94L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.02); catalogued as COSV56282159, COSV56282507; called by muse, mutect2, varscan2
- MAGEA6 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV61448907; called by muse, mutect2, varscan2
- MAGEB4 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.123); catalogued as COSV66775639, COSV66776479; called by muse, varscan2
- MAGEC3 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV53579069; called by muse, mutect2, varscan2
- MAGEL2 | c.2434G>C p.E812Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as COSV58566732, COSV58569055; called by muse, mutect2, varscan2
- ME1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as COSV63838833; called by muse, mutect2, varscan2
- MECOM | c.253C>T p.P85S (on ENST00000468789 / NM_001105078.4; = p.P273S on NM_004991.4) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV52963255; called by muse, mutect2, varscan2
- MGAM | c.5083G>A p.G1695R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.579); catalogued as COSV72074489; called by muse, mutect2, varscan2
- MGP | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57454359; called by muse, mutect2, varscan2
- MMRN1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV53336613; called by muse, varscan2
- MPEG1 | c.986A>T p.K329M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57089978; called by muse, mutect2, varscan2
- MPP7 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV61731621; called by muse, mutect2, varscan2
- MRAP2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV57635621; called by muse, mutect2, varscan2
- MROH2B | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV68183148; called by muse, mutect2, varscan2
- MRPL4 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99459966, COSV99460000; called by muse, mutect2, varscan2
- MUC16 | c.6551C>T p.S2184F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV67461308; called by muse, mutect2, varscan2
- MUC17 | c.7357G>A p.E2453K | Missense Mutation (SNP) | VAF 123/344 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV60286359; called by muse, mutect2, varscan2
- MYH2 | c.2398G>A p.G800R | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55434485, COSV55436280; called by muse, mutect2, varscan2
- MYOM2 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as COSV50703452; called by muse, mutect2, varscan2
- NCAM1 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV57514885; called by muse, mutect2, varscan2
- NHS | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398124606, COSV66273991; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRC4 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.447); catalogued as COSV61592290; called by muse, mutect2, varscan2
- NLRC5 | c.4435G>A p.D1479N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs750242516, COSV52650473, COSV52653810; called by muse, mutect2, varscan2
- NLRP11 | c.2169G>A p.L723= | Splice Region (SNP) | VAF 18/77 reads (23%) | catalogued as COSV64086841; called by muse, mutect2, varscan2
- NLRP4 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100016318; called by muse, mutect2, varscan2
- NLRP4 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100016320; called by muse, mutect2, varscan2
- NOS1 | c.3872C>T p.S1291F | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57610915; called by muse, mutect2, varscan2
- NOX5 | c.1174A>G p.S392G | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV52987823; called by muse, mutect2
- NPBWR2 | c.38G>A p.R13K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV63900026; called by muse, mutect2, varscan2
- NPC1L1 | c.2344C>T p.L782F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.034); catalogued as COSV56924330; called by muse, mutect2, varscan2
- NR4A1 | c.1091T>G p.L364R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54481757; called by muse, mutect2, varscan2
- NSMCE1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as rs748509151, COSV63864185; called by muse, mutect2
- NUP188 | c.3461G>A p.R1154H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs780786880, COSV65361573; called by muse, mutect2, varscan2
- NUTM1 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59216577; called by muse, mutect2, varscan2
- NWD1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.467); catalogued as COSV60337354; called by muse, mutect2, varscan2
- NXPE4 | c.1075G>A p.E359K (on ENST00000375478 / NM_001077639.2; = p.E75K on NM_017678.3) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.117); catalogued as rs768723916, COSV64943678; called by muse, mutect2, varscan2
- OLFML2B | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs1239940075, COSV54195815; called by muse, mutect2, varscan2
- OR10H4 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.367); catalogued as rs374132788, COSV59061163, COSV59061648; called by muse, mutect2, varscan2
- OR10K2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV59221065; called by muse, mutect2, varscan2
- OR11H1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99421808; called by mutect2, varscan2
- OR13C5 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866884938, COSV101053045, COSV66164263; called by muse, mutect2, varscan2
- OR1E1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV59458780; called by muse, mutect2, varscan2
- OR2J3 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV65848937; called by muse, mutect2, varscan2
- OR2T1 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV63541338, COSV63542598; called by muse, mutect2, varscan2
- OR2T11 | c.233T>A p.L78H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58185555; called by muse, mutect2, varscan2
- OR2T12 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58777085; called by muse, mutect2, varscan2
- OR2W1 | c.661A>C p.I221L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV65851550; called by muse, mutect2, varscan2
- OR4C3 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs1190154129, COSV60585241; called by muse, mutect2, varscan2
- OR4E2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV57731638; called by muse, mutect2, varscan2
- OR6Y1 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56929161; called by muse, varscan2
- OR8I2 | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV56167598, COSV56169658; called by muse, mutect2, varscan2
- PAXIP1 | c.2810A>C p.Q937P | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV68185722; called by muse, mutect2, varscan2
- PCDHA1 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65373855; called by muse, mutect2, varscan2
- PCSK5 | c.3152G>A p.G1051E | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.86); catalogued as rs1237053678, COSV70449049; called by muse, mutect2, varscan2
- PDGFRA | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57267262; called by muse, mutect2, varscan2
- PGK1 | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV64831923; called by muse, mutect2, varscan2
- PIK3CB | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 49/275 reads (18%) | catalogued as COSV56683800; called by muse, mutect2, varscan2
- PKD2L2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV51795868, COSV51800113; called by muse, mutect2, varscan2
- PKDREJ | c.5165C>T p.A1722V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99478897; called by muse, mutect2, varscan2
- PLA2G3 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV53208949; called by muse, mutect2, varscan2
- PLB1 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59823458; called by muse, mutect2, varscan2
- PLXNC1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.059); catalogued as COSV51573970; called by muse, mutect2, varscan2
- PMFBP1 | c.1226T>G p.M409R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52822996; called by muse, mutect2, varscan2
- PNLIPRP2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.376); catalogued as COSV53943363; called by muse, mutect2, varscan2
- POTEH | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV100624947; called by muse, mutect2, varscan2
- PPIP5K1 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 34/139 reads (24%) | catalogued as rs373368300; called by muse, mutect2, varscan2
- PPP4R3A | c.2206C>T p.L736F (on ENST00000554943 / NM_001366432.1; = p.L723F on NM_001284280.1) | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV61504252, COSV61505957; called by muse, mutect2, varscan2
- PRKAG2 | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV55227650; called by muse, mutect2, varscan2
- PRKCQ | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54109454; called by muse, mutect2, varscan2
- PRPF4 | c.537G>T p.W179C (on ENST00000374198 / NM_001322267.2; = p.W180C on NM_004697.5) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV65252552; called by muse, mutect2, varscan2
- PSG9 | c.468A>C p.L156F | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as rs1288304074, COSV52484657; called by muse, mutect2, varscan2
- PSKH2 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as rs1239532896, COSV52610161; called by muse, mutect2
- PTGFR | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as COSV66114869; called by muse, mutect2, varscan2
- PTPRD | c.3504+2T>C p.X1168_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | catalogued as COSV61939919; called by muse, mutect2
- PTPRN2 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 50/93 reads (54%) | catalogued as COSV101234433; called by muse, mutect2, varscan2
- PXDNL | c.2981G>A p.G994E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867225480, COSV62485869; called by muse, mutect2, varscan2
- RAG1 | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55024859; called by muse, mutect2, varscan2
- RASA2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as rs944578775, COSV53938966; called by mutect2, varscan2
- RASGRP4 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777144681, COSV53095154, COSV99498513; called by muse, mutect2, varscan2
- RASSF6 | c.613G>A p.E205K (on ENST00000342081 / NM_201431.2; = p.E173K on NM_177532.5) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs767441299, COSV100275064, COSV56717748; called by muse, mutect2, varscan2
- RBFOX1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs774467606, COSV60955865; called by muse, mutect2, varscan2
- RBP3 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.145); catalogued as rs1484072706; called by muse, mutect2, varscan2
- RIMS2 | c.4453G>A p.G1485R (on ENST00000666250 / NM_001348490.2; = p.G1056R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601694, COSV51696438; called by muse, mutect2, varscan2
- RIMS2 | c.4454G>A p.G1485E (on ENST00000666250 / NM_001348490.2; = p.G1056E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99169541, COSV99196588; called by muse, mutect2, varscan2
- RNF152 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV57184134; called by muse, mutect2, varscan2
- RNF214 | c.1220T>C p.M407T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV56118469; called by muse, mutect2, varscan2
- RNGTT | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562304762, COSV55649392; called by muse, mutect2, varscan2
- SAGE1 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100187244; called by muse, mutect2, varscan2
- SAMSN1 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs753527223, COSV53470359, COSV99581996; called by muse, mutect2, varscan2
- SCAF4 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV54586299; called by muse, mutect2, varscan2
- SCN10A | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV71861060; called by muse, mutect2, varscan2
- SCN4A | c.2959G>A p.G987R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.412); catalogued as COSV71126523; called by muse, mutect2, varscan2
- SELP | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1300494354, COSV55250968; called by muse, mutect2, varscan2
- SEMA3E | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754754690, COSV57087131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SF3A2 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.059); catalogued as COSV55554445; called by muse, mutect2, varscan2
- SLC15A1 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.41); catalogued as COSV64731067; called by muse, mutect2, varscan2
- SLC1A2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53520675; called by muse, mutect2, varscan2
- SLC6A19 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV57250804; called by muse, mutect2, varscan2
- SLC9A4 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.034); catalogued as COSV54830252; called by muse, mutect2, varscan2
- SLC9C2 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs267598172, COSV62945331; called by muse, mutect2, varscan2
- SMTN | c.1949C>T p.T650I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV60777478; called by muse, mutect2, varscan2
- SORT1 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 83/308 reads (27%) | catalogued as COSV56665694; called by muse, mutect2, varscan2
- SPATA31D1 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV61194974; called by muse, varscan2
- SPATA31E1 | c.2059G>A p.G687S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV57790975; called by muse, mutect2, varscan2
- SPEF2 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56796115; called by muse, mutect2, varscan2
- SPEN | c.10006C>T p.R3336W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs369486221, COSV65360851; called by muse, mutect2, varscan2
- SPRR1B | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 40/148 reads (27%) | catalogued as COSV61067562, COSV61067916; called by muse, mutect2, varscan2
- SREBF2 | c.2599G>T p.A867S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.436); catalogued as COSV63331022; called by muse, mutect2, varscan2
- STAG3 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV57929433; called by muse, mutect2, varscan2
- STK31 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV63455221, COSV63455571; called by muse, mutect2, varscan2
- TACR3 | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV59200578; called by muse, mutect2, varscan2
- TAGAP | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV57851329; called by muse, mutect2, varscan2
- TBL3 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV60341298; called by muse, mutect2, varscan2
- TERT | c.2633C>T p.T878I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); catalogued as COSV57211192, COSV57222029; called by mutect2, varscan2
- TERT | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 147/315 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV57211199; called by muse, mutect2, varscan2
- TEX13A | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as COSV61153346, COSV61184135; called by muse, mutect2, varscan2
- TG | c.3955G>A p.V1319I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV55073214; called by muse, mutect2, varscan2
- THRA | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV52842312; called by muse, mutect2, varscan2
- TKTL2 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54918449; called by muse, mutect2, varscan2
- TLL1 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as rs1019855568, COSV50274256, COSV50284655; called by muse, mutect2, varscan2
- TMEM175 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV53278451, COSV99297616; called by muse, mutect2, varscan2
- TMEM251 | c.479T>C p.L160P (on ENST00000415050 / NM_001098621.4; = p.L128P on NM_015676.3) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV52092469; called by muse, mutect2, varscan2
- TMLHE | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57687081; called by muse, mutect2, varscan2
- TMPRSS11F | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as rs1157766870, COSV62466056; called by muse, mutect2, varscan2
- TOM1L2 | c.1058C>T p.S353F (on ENST00000379504 / NM_001350333.2; = p.S303F on NM_001033551.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs978993333, COSV58885629; called by muse, mutect2, varscan2
- TOP1MT | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs377591039; called by muse, mutect2, varscan2
- TRAF2 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56037504; called by muse, mutect2, varscan2
- TSC22D1 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1233969793, COSV71775541; called by muse, mutect2, varscan2
- TUSC3 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV101140732, COSV65880512; called by muse, mutect2, varscan2
- TXNDC15 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV64379509; called by muse, mutect2, varscan2
- UBA6 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV59176428; called by muse, mutect2, varscan2
- UGT1A9 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60836896; called by muse, mutect2, varscan2
- USH2A | c.9427T>A p.Y3143N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56359120, COSV56383633; called by muse, mutect2, varscan2
- VPS11 | c.247C>T p.L83F (on ENST00000620429; = p.L627F on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); catalogued as rs764773254, COSV100333777; called by muse, mutect2, varscan2
- VPS13A | c.924G>T p.M308I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62428475; called by muse, mutect2, varscan2
- WDR82 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56601188, COSV56601514; called by muse, mutect2, varscan2
- XIRP1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.535); catalogued as COSV100453652, COSV100453896; called by muse, mutect2, varscan2
- XIRP2 | c.2807C>T p.S936L (on ENST00000628543; = p.S1111L on NM_152381.6) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs771644507, COSV54695141; called by muse, mutect2, varscan2
- ZFX | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58447225, COSV58447776; called by muse, mutect2, varscan2
- ZIM3 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.192); catalogued as COSV54141959; called by muse, mutect2, varscan2
- ZNF121 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.634); catalogued as rs267605827, COSV100248166; called by mutect2, varscan2
- ZNF777 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV56096276; called by muse, mutect2, varscan2
- ZNF831 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV64038358; called by muse, mutect2
- ZNF831 | c.3661C>T p.P1221S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV64039349; called by muse, mutect2, varscan2
- DPY19L2 | c.1311_1318del p.I438Efs*6 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- FPR1 | c.409_421del p.R137Wfs*5 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.811A>C p.K271Q | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- RAB11FIP2 | c.87del p.S31Vfs*9 | Frame Shift Del (DEL) | VAF 31/180 reads (17%) | called by mutect2, pindel, varscan2
- SIGLEC8 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRBV3-1 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, varscan2
- ABCA2 | c.2190C>T p.F730= (on ENST00000614293; = p.F700= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV55800208, COSV55807917; called by mutect2, varscan2
- ACAP2 | c.1305C>T p.I435= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as rs527269230, COSV58750805; called by muse, mutect2, varscan2
- ADAMTS19 | c.1827C>T p.T609= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV50731551; called by muse, mutect2, varscan2
- ADGRG4 | c.8892G>A p.R2964= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as COSV54952190; called by muse, mutect2, varscan2
- APLP1 | c.1896C>T p.R632= (on ENST00000221891 / NM_001024807.3; = p.R631= on NM_005166.4) | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs967695893, COSV55702950; called by muse, mutect2, varscan2
- ARHGAP30 | c.2880A>G p.A960= (on ENST00000368013 / NM_001025598.2; = p.A749= on NM_181720.3) | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV63515998; called by muse, mutect2, varscan2
- ATP13A4 | c.1797C>T p.F599= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV55068545; called by muse, mutect2, varscan2
- ATP8A2 | c.2187C>T p.I729= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV54947909; called by muse, mutect2, varscan2
- ATRX | c.6054G>A p.G2018= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV64875160; called by muse, mutect2, varscan2
- B3GNT2 | c.537C>T p.V179= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV57344460; called by muse, mutect2, varscan2
- BRAT1 | c.2109C>T p.F703= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs745775567, COSV61395061; called by muse, mutect2, varscan2
- BRINP2 | c.645C>T p.I215= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV64177063, COSV64180092; called by muse, mutect2, varscan2
- C4orf51 | c.258C>T p.A86= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV71264116; called by muse, mutect2, varscan2
- CACNA1I | c.4587C>T p.V1529= | Silent (SNP) | VAF 40/199 reads (20%) | catalogued as COSV60806170; called by muse, mutect2, varscan2
- CATSPER3 | c.489C>T p.I163= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV50945704; called by muse, mutect2, varscan2
- CAVIN2 | c.1227C>T p.S409= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs767951134, COSV58423926; called by muse, mutect2, varscan2
- CD300C | c.615G>A p.V205= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV58170096; called by muse, mutect2, varscan2
- CDA | c.261C>T p.I87= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs376525928; called by muse, mutect2, varscan2
- CDH8 | c.2313G>A p.Q771= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1357363423, COSV54862184; called by muse, mutect2, varscan2
- COL22A1 | c.2052C>A p.G684= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV57333461; called by muse, mutect2, varscan2
- COL6A3 | c.3357C>T p.I1119= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV55087088; called by muse, mutect2, varscan2
- CSMD2 | c.5670C>T p.I1890= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV53904435; called by muse, mutect2, varscan2
- CUX2 | c.3516G>A p.R1172= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs754002548, COSV99919666; called by muse, mutect2, varscan2
- CX3CR1 | c.78C>T p.I26= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs759347804, COSV64193670, COSV64194275; called by muse, mutect2, varscan2
- CYP2C8 | c.1143C>T p.I381= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100987878, COSV64876851; called by muse, mutect2, varscan2
- DCC | c.3027C>T p.I1009= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV59098313; called by muse, mutect2, varscan2
- DHTKD1 | c.2064C>T p.L688= | Silent (SNP) | VAF 63/265 reads (24%) | catalogued as rs1266698260, COSV53803029; called by muse, mutect2, varscan2
- DNAH2 | c.8088C>T p.F2696= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs1404923311, COSV66718700; called by muse, mutect2, varscan2
- DNAH3 | c.8727G>A p.R2909= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as COSV54516934; called by muse, mutect2, varscan2
- DNAH7 | c.10752C>T p.F3584= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100417516, COSV56760945; called by muse, mutect2, varscan2
- DNAJC5G | c.201G>A p.G67= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV56079856; called by muse, mutect2, varscan2
- DNER | c.738A>T p.G246= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV59164452; called by muse, mutect2, varscan2
- DSCAM | c.2913C>A p.P971= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV68025365; called by muse, mutect2, varscan2
- EDNRA | c.441T>G p.P147= | Silent (SNP) | VAF 41/148 reads (28%) | catalogued as COSV60097064; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2067C>T p.I689= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as rs750670890, COSV62567416; called by muse, mutect2, varscan2
- ENPP5 | c.225C>T p.N75= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs1447904877, COSV57908505; called by muse, mutect2, varscan2
- ENPP6 | c.396G>A p.R132= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs554371820, COSV57066008; called by muse, mutect2, varscan2
- EPHA4 | c.2001C>T p.F667= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV56031146; called by muse, mutect2, varscan2
- EPHB2 | c.729G>A p.G243= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV65861985; called by muse, mutect2, varscan2
- EPS8L3 | c.795G>A p.R265= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs1312814738, COSV62609275; called by muse, mutect2, varscan2
- ERBB4 | c.2553G>A p.V851= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV61481265; called by muse, mutect2, varscan2
- ERC1 | c.426C>T p.S142= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV61693981; called by muse, mutect2, varscan2
- EVA1B | c.345G>A p.S115= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV54634028; called by muse, varscan2
- EVPL | c.4572C>T p.I1524= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV56909956; called by muse, mutect2, varscan2
- FAM47C | c.2760G>A p.G920= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV63725982; called by muse, mutect2, varscan2
- FLG2 | c.4260G>A p.R1420= | Silent (SNP) | VAF 60/203 reads (30%) | catalogued as COSV66167227; called by muse, mutect2, varscan2
- FLNA | c.810G>A p.K270= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs1407974004, COSV61041661; called by muse, mutect2, varscan2
- FNDC3B | c.1119C>T p.T373= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV61040853; called by muse, mutect2, varscan2
- FOXP4 | c.1320G>A p.R440= (on ENST00000307972 / NM_001012426.1; = p.R427= on NM_138457.3) | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs1315476175, COSV57219601; called by muse, mutect2, varscan2
- FUT9 | c.387G>A p.Q129= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV56145617; called by muse, mutect2, varscan2
- GAL3ST1 | c.742C>T p.L248= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs1323015760, COSV100143078; called by muse, mutect2, varscan2
- GALNT5 | c.1305C>T p.P435= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52037332; called by muse, mutect2, varscan2
- GCNT3 | c.1062C>T p.I354= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV68532157; called by muse, mutect2, varscan2
- GLCE | c.1695C>T p.F565= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV55945455; called by muse, mutect2, varscan2
- GPR34 | c.753G>A p.R251= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV59365417; called by muse, mutect2, varscan2
- GRM5 | c.2340G>A p.T780= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs199916630, COSV59601835; ClinVar: likely benign; called by muse, mutect2, varscan2
- GSTK1 | c.354C>T p.S118= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV64424204; called by muse, mutect2
- GUCY1A2 | c.390C>T p.F130= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV56477660; called by muse, mutect2, varscan2
- HAS1 | c.804G>A p.R268= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV55787147; called by muse, mutect2, varscan2
- HOXB5 | c.702C>T p.S234= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as rs140096647, COSV53312575; called by muse, mutect2, varscan2
- IDH3G | c.591C>T p.S197= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV54207139; called by muse, mutect2, varscan2
- IGKV1D-43 | c.210C>T p.I70= | Silent (SNP) | VAF 39/173 reads (23%) | called by muse, mutect2, varscan2
- INTS10 | c.1353C>T p.F451= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV67604046; called by muse, mutect2, varscan2
- ITGA2B | c.1845C>T p.V615= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as rs199556555, COSV52232204; called by muse, mutect2, varscan2
- KCNG4 | c.1317C>T p.I439= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs971575759, COSV57583484; called by muse, mutect2, varscan2
- KLK13 | c.801C>T p.T267= | Silent (SNP) | VAF 55/206 reads (27%) | catalogued as COSV50067006; called by muse, mutect2, varscan2
- LDB2 | c.780G>A p.R260= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV58767498; called by muse, mutect2, varscan2
- LRCH1 | c.417C>T p.I139= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs201744827, COSV60846568; called by muse, mutect2, varscan2
- LRP1B | c.8385C>T p.S2795= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV67208697; called by muse, mutect2, varscan2
- LRRK2 | c.1431G>A p.L477= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV54150516; called by muse, mutect2, varscan2
- MAGEB18 | c.372G>A p.T124= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs773395698, COSV57463775; called by muse, mutect2
- MOSPD2 | c.240T>A p.L80= | Silent (SNP) | VAF 55/204 reads (27%) | catalogued as COSV66859925; called by muse, mutect2, varscan2
- MRPL4 | c.807G>A p.L269= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs767151772, COSV99459997; called by muse, mutect2, varscan2
- MTNR1A | c.705G>A p.R235= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV56155639, COSV56156629; called by muse, mutect2, varscan2
- MUC16 | c.2700C>T p.T900= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV67461315; called by muse, mutect2, varscan2
- MUC17 | c.387C>T p.F129= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs775546915, COSV60286352; called by muse, mutect2, varscan2
- MUC5B | c.3606C>T p.P1202= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1017974151, COSV71591557; called by muse, mutect2, varscan2
- NEB | c.3291G>A p.G1097= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV51134294; called by muse, mutect2, varscan2
- NME8 | c.774C>T p.V258= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs764505957, COSV52249250; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPR1 | c.2697C>T p.T899= | Silent (SNP) | VAF 24/112 reads (21%) | catalogued as rs139666221; called by muse, mutect2, varscan2
- OLFM4 | c.60G>A p.G20= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as COSV54576918; called by muse, mutect2, varscan2
- OPTC | c.459G>A p.R153= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV65867630; called by muse, mutect2, varscan2
- OR2AT4 | c.432G>A p.Q144= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV59406829; called by mutect2, varscan2
- OR4A47 | c.177C>T p.F59= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV101487065; called by muse, mutect2, varscan2
- OR4K14 | c.81C>T p.F27= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV59292649; called by muse, mutect2, varscan2
- OR5L2 | c.855G>A p.L285= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV65723464; called by mutect2, varscan2
- OTOGL | c.3894G>A p.E1298= (on ENST00000547103; = p.E1289= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV72006486; called by muse, mutect2, varscan2
- PADI4 | c.1431C>T p.S477= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs988556909, COSV64923831; called by muse, mutect2, varscan2
- PAPSS2 | c.66C>T p.A22= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs1355480930, COSV63263217; called by muse, mutect2, varscan2
- PCYT1A | c.600C>T p.I200= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV53057223, COSV99492009; called by muse, mutect2, varscan2
- PDP2 | c.627C>T p.L209= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV61240435; called by muse, mutect2, varscan2
- PKD1L1 | c.5886C>T p.S1962= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1434965601, COSV56963126; called by muse, mutect2, varscan2
- PKHD1L1 | c.4623C>T p.P1541= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs375837903, COSV101006187; called by mutect2, varscan2
- PLD2 | c.285C>T p.D95= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as COSV54005459; called by muse, mutect2, varscan2
- PLXNA4 | c.1488C>T p.I496= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs866363810, COSV58119342, COSV58154684; called by muse, mutect2, varscan2
- PNPLA7 | c.903C>T p.L301= | Silent (SNP) | VAF 41/164 reads (25%) | catalogued as rs765301642, COSV52997748; called by muse, mutect2, varscan2
- POF1B | c.411G>A p.R137= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV53132651; called by muse, mutect2, varscan2
- PTGS2 | c.438G>A p.P146= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs201238353; called by muse, mutect2, varscan2
- PTPRB | c.5598G>C p.T1866= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV54238841, COSV54241077, COSV54250042; called by muse, mutect2, varscan2
- PTPRD | c.2289C>T p.P763= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV61939935; called by muse, mutect2, varscan2
- PTPRN2 | c.486C>T p.S162= | Silent (SNP) | VAF 52/97 reads (54%) | catalogued as rs141519128; called by muse, mutect2, varscan2
- RELN | c.8541C>T p.I2847= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs746020620, COSV58997840; called by muse, mutect2, varscan2
- REPS2 | c.1659G>A p.K553= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV58181271; called by muse, mutect2, varscan2
- SAGE1 | c.1986C>T p.S662= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV100187247; called by muse, mutect2, varscan2
- SCN2A | c.3573G>A p.G1191= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs267598962, COSV51838673; called by muse, mutect2, varscan2
- SHCBP1L | c.1116G>A p.R372= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV62354570; called by mutect2, varscan2
- SHOC1 | c.2148G>A p.K716= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV59497698, COSV59500207; called by muse, mutect2, varscan2
- SLC14A2 | c.1320G>A p.V440= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV99675506; called by muse, mutect2, varscan2
- SLC6A14 | c.69G>A p.E23= | Silent (SNP) | VAF 63/230 reads (27%) | catalogued as COSV64146832; called by muse, mutect2, varscan2
- SP140 | c.2298C>T p.L766= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100613282; called by muse, mutect2, varscan2
- SYNGR1 | c.351C>T p.F117= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV53368131; called by muse, mutect2, varscan2
- TACC2 | c.4569C>T p.P1523= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100552325, COSV57753363; called by muse, mutect2, varscan2
- TACR3 | c.822C>T p.L274= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV59200572; called by muse, mutect2, varscan2
- TENM3 | c.3573C>T p.F1191= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV69303912; called by muse, mutect2, varscan2
- TENM4 | c.6219G>A p.E2073= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV53623217; called by muse, mutect2, varscan2
- THADA | c.948C>T p.A316= | Silent (SNP) | VAF 96/344 reads (28%) | catalogued as rs1447534176, COSV57681811; called by muse, mutect2, varscan2
- THEMIS | c.1071C>T p.I357= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs146173025, COSV64069646; called by muse, mutect2, varscan2
- TMEM131 | c.1908T>C p.L636= | Silent (SNP) | VAF 61/216 reads (28%) | catalogued as COSV51774229; called by muse, mutect2, varscan2
- TMEM200A | c.1011C>T p.S337= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1435968397, COSV51652069; called by muse, mutect2, varscan2
- TNRC6C | c.2476C>T p.L826= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV56943811; called by muse, mutect2, varscan2
- TTC17 | c.792C>A p.A264= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV50007888; called by muse, mutect2, varscan2
- TTN | c.17514C>T p.S5838= (on ENST00000591111; = p.S4911= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV60001781; called by muse, mutect2, varscan2
- USP13 | c.1731C>T p.F577= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV55864963; called by muse, mutect2, varscan2
- USP53 | c.1965C>T p.S655= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1008736295, COSV56793915; called by muse, mutect2, varscan2
- VN1R2 | c.309G>A p.G103= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV59037265; called by muse, mutect2
- VPS11 | c.246C>T p.L82= (on ENST00000620429; = p.L626= on NM_021729.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as rs782513138, COSV100333773; called by muse, mutect2, varscan2
- VSTM4 | c.339C>T p.S113= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs151199777, COSV53677586; called by muse, mutect2, varscan2
- WBP2NL | c.771C>T p.L257= | Silent (SNP) | VAF 48/182 reads (26%) | catalogued as rs769982167, COSV60919196; called by muse, mutect2, varscan2
- XAB2 | c.450C>T p.P150= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV60697154, COSV60697547; called by muse, mutect2, varscan2
- ZKSCAN1 | c.69C>T p.I23= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs767802425, COSV60873748; called by muse, mutect2, varscan2
- ZNF121 | c.261C>T p.S87= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs267605826, COSV100248049, COSV100248164; called by mutect2, varscan2
- ZNF354C | c.243C>T p.T81= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV59608032; called by muse, mutect2, varscan2
- ZSCAN5B | c.1392G>A p.E464= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV61999744; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851500 G>A | 3'Flank (SNP) | VAF 49/144 reads (34%) | called by muse, mutect2, varscan2
- DNAH10 | c.3450+10C>T | Intron (SNP) | VAF 9/33 reads (27%) | catalogued as rs755814633; called by muse, mutect2, varscan2
- KIR3DX1 | n.202G>A | RNA (SNP) | VAF 3/23 reads (13%) | catalogued as COSV55597985; called by muse, mutect2
- MIR323B | n.9G>A | RNA (SNP) | VAF 8/32 reads (25%) | catalogued as rs775788634; called by muse, mutect2, varscan2
- SECISBP2 | chr9:89363498 C>T | 3'Flank (SNP) | VAF 17/45 reads (38%) | catalogued as rs745842598, COSV59393805; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2276G>A | Intron (SNP) | VAF 13/79 reads (16%) | catalogued as rs1172447361, COSV100314253; called by muse, mutect2, varscan2
- USP35 | c.-2C>T | 5'UTR (SNP) | VAF 20/66 reads (30%) | catalogued as rs371777394; called by muse, mutect2, varscan2
- XIST | n.8367G>A | RNA (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
